Surgical pathology report (de-identified scan), TCGA case TCGA-G4-6320, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-G4-6320-01A (Primary Tumor).

[page 1 of 2]
SPECIMENS:

A. RIGHT COLON

SPECIMEN(S):

A. RIGHT COLON

INTRAOPERATIVE CONSULTATION DIAGNOSIS:

A-right colon: Tumor is 11 cm from each margin (proximal and distal) called by

GROSS DESCRIPTION:

A. RIGHT COLON

Received fresh is a closed segment of colon including terminal ileum, ileocecal valve, cecum, and colon measuring 25 cm in length. The serosa has an area of tattooing approximately 7 cm from the distal margin. The vermiform appendix is 7.1 cm in length and 0.5 cm in width; it is unremarkable. On opening the colon, the segment of terminal ileum is 6 cm in length and 4 cm in diameter; right colon is 19 cm in length and up to 10 cm in diameter. The colon contains a circumferential, polypoid, indurated, mass with serpentine borders measuring 6 x 4.3 cm extending through the muscularis propria. The mass is located 11 cm from the proximal and distal margins and 5 cm from ileocecal valve. There are 2 colonic polyps, 0.5 and 0.6 cm. Tissue is procured. Representative sections are submitted as follows:

A1: proximal margin

A2: distal margin

A3-A8: mass in relationship with normal mucosal and deep margin

A9: colonic polyps

A10: normal-appearing mucosa including region of tattooing

A11: appendix

A12: proximal, 6 lymph nodes

A13: proximal, 2 lymph nodes

A14-A15: proximal, 1 node each

A16-A23: distal, 6 lymph nodes each

A24-A25: distal, 3 lymph nodes each

A26-A27: distal, 2 lymph nodes each

A28-A33: distal, 1 lymph node each

A34-A36: 7 possible lymph nodes each (after O-Fix)

DIAGNOSIS:

COLON, RIGHT, HEMICOLECTOMY:

- INVASIVE ADENOCARCINOMA, MODERATELY DIFFERENTIATED, ARISING IN A TUBULOVILLOUS ADENOMA.
- TUMOR MEASURES 6 CM.
- TUMOR INVOLVES THE SUBSEROSAL FAT.
- MARGINS, FREE OF TUMOR.
- HYPERPLASTIC POLYPS (2).
- APPENDIX, NO TUMOR SEEN.
- METASTATIC CARCINOMA TO TWO OF 65 LYMPH NODES WITH FOCAL EXTRANODAL EXTENSION (2/65).

SYNOPTIC REPORT - COLON & RECTUM

Specimen Type: Right hemicolectomy

Tumor Site: Hepatic flexure

Tumor Configuration: Infiltrative

Ulcerating

Tumor size: 6cm

WHO Classification

Adenocarcinoma 8140/3

Histologic Grade: G2: Moderately differentiated

Extent of Invasion: Subserosa

Margins: Margin(s) uninvolved by invasive carcinoma (Proximal, Distal, Radial)

Venous/Lymphatic Invasion: Present

Perineural Invasion: Absent

Additional Pathologic Findings: Adenoma

Extent of Resection: R0: Complete resection with grossly and microscopically negative margins

[page 2 of 2]
[REDACTED]

Lymph Nodes: Positive 2 / 65
Extranodal extension: Present
Implants: Absent
Pathological Staging (pTNM): pT 3 N 1 M X

CLINICAL HISTORY:

None given

PRE-OPERATIVE DIAGNOSIS:

Colon cancer

[REDACTED]

Source: NCI Genomic Data Commons file a589acb3-4446-4d53-bab3-0dd65b4d714c (TCGA-G4-6320.C0C529DA-076F-4843-8DFE-CADC1B651A71.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).